Surgical pathology report (de-identified scan), TCGA case TCGA-NH-A6GC, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Candler, specimen TCGA-NH-A6GC-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

User:

PATIENT

ACCT #:

ROOM:

REG

REG DR:

AGE/SX:

BED:

DIS:

DOB:

STATUS:

SPEC #

RECD:

STATUS:

COLL:

TIME IN FORMALIN: 6:26

hrs.

COLD ISCHEMIA TIME: 0:00

mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Colon cancer

Remarks:

Specimen(s): A. Omental implant
B. Left colon
C. METs

ICD-O-3

Adenocarcinoma, mucinous NOS

8480/3

Site: Descending colon C18.6

QW 6/13/13

MICROSCOPIC DIAGNOSIS:

met

A. OMENTAL IMPLANT RESECTION:
- METASTATIC MUCINOUS ADENOCARCINOMA CONSISTENT WITH COLON PRIMARY

B. LEFT COLON, LEFT HEMICOLECTOMY:
- MUCINOUS ADENOCARCINOMA OF THE DESCENDING COLON POSSIBLY ARISING IN TUBULOVILLOUS
- ADENOMA
- CARCINOMA INVADERS THROUGH COLON WALL INTO SUBSEROSAL ADIPOSE TISSUE AND EXTENDS
- TO WITHIN 1 MM OF PERITONEAL SURFACE AND RADIAL MARGIN
- TUMOR ADHERENT TO ABDOMINAL WALL BY CLINICAL HISTORY
- SURGICAL MARGINS OF RESECTION FREE OF TUMOR WITH CLOSEST MARGIN RADIAL MARGIN
- 1 MM
- METASTATIC MUCINOUS ADENOCARCINOMA IN THREE (3) OF NINETEEN (19) SUBSEROSAL LYMPH
- NODES
- LYMPH-VASCULAR INVASION NOT IDENTIFIED
- SEE COMMENT FOR SURGICAL PATHOLOGY CANCER CASE SUMMARY CHECKLIST

C. PERITONEAL METASTASES, RESECTION:
- MUCINOUS ADENOCARCINOMA CONSISTENT WITH METASTATIC COLON CARCINOMA

COMMENT(S)

At request of the specimen will be forwarded for KRAS analysis. Results will be reported as an addendum when complete.

SURGICAL PATHOLOGY CANCER CASE SUMMARY - APPROVED BY COLLEGE OF AMERICAN PATHOLOGISTS

SPECIMEN:

Descending colon

PROCEDURE:

Left hemicolectomy

TUMOR SITE:

Left (descending) colon

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 2

User:

SPEC #:

PATIENT:

(Continued)

COMMENT(S)

(Continued)

TUMOR SIZE: 8.0 cm
MACROSCOPIC TUMOR PERFORATION: Not identified
HISTOLOGIC TYPE: Mucinous adenocarcinoma
HISTOLOGIC GRADE: Low-grade
MICROSCOPIC TUMOR EXTENSION: Tumor is adherent to other organs or structures, abdominal wall
MARGINS: If all margins uninvolved by invasive carcinoma.
distance of invasive carcinoma from closest margin: 1 mm, radial
Proximal margin: uninvolved by invasive carcinoma
Distal margin: uninvolved by invasive carcinoma
Circumferential margin: uninvolved by invasive carcinoma
TREATMENT EFFECT: No prior treatment
LYMPH-VASCULAR INVASION: Not identified
PERINEURAL INVASION: Not identified
TUMOR DEPOSITS: Not identified
TYPE OF POLYP IN WHICH INVASIVE CARCINOMA AROSE: Tubulovillous adenoma - possible
PATHOLOGIC STAGING: Primary tumor: pT4b
Regional lymph nodes: pN1b
Number of lymph nodes examined: 19
Number of lymph nodes involved: 3
Distant metastasis: pM1b, omentum and peritoneum
KRAS mutational analysis pending
ANCILLARY STUDIES:

GROSS DESCRIPTION:

The specimen is received in three parts. Each part is labeled with the patient's name.

A. Labeled "omental implant" is received fresh for frozen section diagnosis and is a 9.0 x 6.0 x 2.5 cm diffusely indurated, nodular portion of yellow, lobulated omental adipose. The adipose has multiple, mucinous tumor masses with two large masses ranging up to 6.0 x 4.5 x 2.5 cm. The section is sampled for frozen section diagnosis. The tissue is sampled to have solid to minutely cystic, mucin-filled masses throughout the specimen. A section is sampled for frozen section diagnosis. An additional section is sampled for tissue banking. Additional representative sections are sampled from across the specimen:

- A1 - frozen section residue
- A2-A4 - additional sections sampled

B. Labeled "left colon" and received fresh for tissue banking is a 23 cm segment of large bowel. The bowel has a distal area of indurated, creeping fat. This region is inked blue on the serosa. The bowel is opened to have an 8.0 x 7.0 x 3.0 cm mucinous tumor mass. The mass comes to within 4.5 cm of the distal margin, 14 cm from proximal. The tumor diffusely involves and extends through the bowel wall and extends close to the inked serosa and mesenteric, radial fat margin. There is 1.5 cm of adipose between the bowel wall and radial fat margin. The tumor extends nearly to this inked margin. Surrounding mucosa is otherwise unremarkable with normal, tan folds. The adipose is sectioned to have multiple nodular lymph nodes. The lymph nodes are focally tumor replaced with a mucinous appearing cut

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE
RUN TIME?
RUN USER:

PAGE 3

User

SPEC #

PATIENT:

Continued)

GROSS DESCRIPTION: (Continued)

surface. Sections of the tumor are sampled for tissue banking. Representative sections are sampled for routine histology as labeled:

- B1 - proximal margin
- B2 - distal margin
- B3-B7 - sections of tumor extending through bowel wall into underlying adipose to the inked serosal and radial fat margin
- B8-B11 - whole lymph nodes from proximal to distal
- B12 - tumor replaced lymph node sampled

C. Labeled "METS" and received in formalin is a 5.0 x 3.0 x 2.0 cm portion of yellow adipose. The adipose has two mucinous tumor nodules at either pole. The smaller nodule is 1.0 cm and the larger nodule is 2.3 x 2.3 x 1.7 cm. Representative sections are sampled to include normal, adjacent omental adipose cassettes C1-C2.

MICROSCOPIC DESCRIPTION:

The slides are examined and evaluated.

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS, OMENTAL IMPLANT:

- METASTATIC ADENOCARCINOMA

PHOTO DOCUMENTATION

Image
Image
Image
Image
Image

Signed ____ (signature on file) ____

** END OF REPORT **

Equal Malignancy History		✓

Source: NCI Genomic Data Commons file 9a63e64d-6c46-45aa-9ec8-46298efaef2b (TCGA-NH-A6GC.B4D412AD-FD5C-4397-B56E-62F39A375751.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).